Surgical pathology report (de-identified scan), TCGA case TCGA-MQ-A4KX, project TCGA-MESO (Mesothelioma), tissue source site Washington University - NYU, specimen TCGA-MQ-A4KX-01A (Primary Tumor).

[page 1 of 3]
Result type: Report
Result date:
Result status: Modified
Result title: SPECIMEN DESCRIPTION
Performed by:

*** Final Report ***

ICD-0-3

SPECIMEN DESCRIPTION

RIGHT PLEURA
LYMPH NODE NO 7 LEVEL
LEVEL 4 LYMPH NODE
INTERNAL MAMMARY NODES

Mesothelioma, epithelioid, NOS 9052/3
Site: pleura, NOS c38.4 *fw*
10/4/12

SURGICAL PATHOLOGY REPORT

LOCATION: [REDACTED]

PATHOLOGY NO.: [REDACTED]
HOSPITAL ID: [REDACTED]
PATIENT ID: [REDACTED]

HOSPITAL NO.: [REDACTED]
ACCOUNT NO.: [REDACTED]
DATE RECEIVED:
DATE OF PROCEDURE:
ACCN REQ. NO.: NOT GIVEN
ATTENDING PHYS:

PATIENT'S NAME: [REDACTED]
AGE/SEX/DOB: M
PHYSICIAN(S):
COPY TO:
REFERRING PHYS:

DIAGNOSIS:

A. PLEURA, PLEURECTOMY: MALIGNANT MESOTHELIOMA, EPITHELIAL TYPE WITH TUBULOPAPILLARY PATTERN(SEE COMMENT).
NO INVASION OF UNDERLYING PULMONARY PARENCHYMA.
NO DEFINITE VASCULAR SPACE INVASION NOTED.

B. LYMPH NODES LEVEL 7: MULTIPLE FRAGMENTS OF LYMPH NODES WITH HYALINIZED FIBROTIC GRANULOMATOUS NODULES AND ANTHRACOSIS. NEGATIVE FOR METASTATIC NEOPLASM.

C. LEVEL 4 LYMPH NODE: THREE LYMPH NODES WITH ANTHRACOSIS AND OCCASIONAL HYALINIZED FIBROTIC NODULE. NEGATIVE FOR METASTATIC NEOPLASM.

D. INTERNAL MAMMARY NODE: ONE SMALL LYMPH NODE AND ADJACENT FIBROMUSCULAR AND ADIPOSE TISSUE, ALL NEGATIVE FOR MALIGNANT NEOPLASM.

COMMENT: Specimen A. The histological features involving the pleura are consistent with malignant mesothelioma however the confirmatory immunoperoxidase stains are pending. A supplemental report will follow. Also the special stains for fungus and acid fast bacilli are pending on specimen B.

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 2 of 3]
[REDACTED]

SPECIMEN: A RIGHT PLEURA
B LYMPH NODE NO 7 LEVEL
C LEVEL 4 LYMPH NODE
D INTERNAL MAMMARY NODES
OPERATION: RIGHT PNEUMONECTOMY/PLEURECTOMY
PRE-OP DIAGNOSIS: MESOTHELIOMA
POST-OP DIAGNOSIS: SAME
CLINICAL DATA: NOT GIVEN

GROSS DESCRIPTION:

A. Received fresh labeled right pleura the specimen consists of three fragments of parietal pleura that range in size from 19.5 x 4.0 x 0.3 cm to 45.0 x 17.0 x 0.3 cm. The surface is tan to red, smooth and glistening with focal petechial hemorrhages. Multiple firm, round tan nodules are palpated that range in greatest dimension from 0.2 to 0.7 cm. One piece of the pleura shows a surface that is ragged, brown and also contains multiple firm nodules. On the other surface of the same piece some strips of skeletal muscle are identified. The specimen is serially sectioned to reveal portions of the lung surrounded by firm white sheets. Representative sections are submitted in 10 cassettes.

B. Received fresh labeled level 7 lymph node the specimen consists of three fragments of dark red to black firm tissue ranging in size from 1.2 x 1.0 x 0.5 cm to 3.0 x 2.0 x 1.0 cm. One segment shows multiple tan-white nodules on the cut surface that measure, on average, 0.2 cm in greatest dimension. The specimen is submitted in toto in six cassettes.

C. Received fresh labeled level 4 lymph node the specimen consists of three possible anthracotic lymph nodes that range in size from 0.4 x 0.3 x 0.1 cm to 0.6 x 0.5 x 0.2 cm. The specimen is submitted in toto in one cassette.

D. Received fresh labeled internal mammary nodes the specimen consists of one piece of yellow to pink soft tissue measuring 1.2 x 1.5 x 0.2 cm. The specimen is inspected for lymph nodes. One possible lymph node is identified measuring 0.5 cm in greatest dimension. The specimen is submitted in toto in one cassette.

SPECIAL STAIN: Immunoperoxidase keratin, CEA, calretinin, thrombomodulin, B72.3, BerEP4, Gms, Acidfast Stains.
CPT CODE: [REDACTED]

ELECTRONIC SIGNATURE:

SURGICAL PATHOLOGY REPORT

LOCATION:

PATHOLOGY NO.: [REDACTED]
HOSPITAL ID.: [REDACTED]
PATIENT ID: [REDACTED]

HOSPITAL NO.: [REDACTED]

PATIENT'S NAME: [REDACTED]

Printed by:
Printed on:

Page 2 of 3
(Continued)

[page 3 of 3]
ACCOUNT NO.: [REDACTED]
DATE RECEIVED:
DATE OF PROCEDURE:
ACCN REQ. NO.: NOT GIVEN
ATTENDING PHYS:

AGE/SEX/DOB: M
PHYSICIAN(S):
COPY TO:
REFERRING PHYS:

ADDENDUM REPORT

The neoplastic cells stain strongly positive with immunoperoxidase keratin, calretinin and mildly positive with thrombomodulin stain and essentially negative with CD15, CEA, B73.2 and BERP-4 stains. This staining pattern supports the diagnosis of mesothelioma over carcinoma.

SPECIMEN: A RIGHT PLEURA
B LYMPH NODE NO 7 LEVEL
C LEVEL 4 LYMPH NODE
D INTERNAL MAMMARY NODES
OPERATION: RIGHT PNEUMONECTOMY/PLEURECTOMY
PRE-OP DIAGNOSIS:
POST-OP DIAGNOSIS: SAME
CLINICAL DATA: NOT GIVEN
CPT CODE:

ELECTRONIC SIGNATURE:

Completed Action List:

* Perform by

Page 3 of 3
(End of Report)

Printed by:
Printed on:

Source: NCI Genomic Data Commons file 0cf92002-0876-414a-a86d-43d999b4d55a (TCGA-MQ-A4KX.22C75817-2D45-433A-8838-0E02FC00D12A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).